Gene-level copy-number profile of tumor specimen TCGA-13-1481-01A from TCGA case TCGA-13-1481, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 76.4 years (27,898 days).
Specimen TCGA-13-1481-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.69a7fc68-d6f9-4804-87d1-693346e176e8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1481-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d6cd77e1-e659-40ee-a0b1-41252ed8c76f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,515; copy number 2: 14,806; copy number 3: 19,451; copy number 4: 16,446; copy number 5: 4,349; copy number 6: 2,435; copy number 7: 603; copy number 8: 105; copy number 9: 104.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-1481-01A-01D-0472-01): tumor purity 0.65, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 812 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:172,323,260–192,776,899, 315 genes, copy number 7 (broad region; genes not listed).
- chr3:158,841,093–177,011,067, 214 genes, copy number 7–9 (broad region; genes not listed).
- chr5:28,213,359–41,968,366, 221 genes, copy number 7 (broad region; genes not listed).
- chr8:116,950,273–117,176,714, 1 gene, copy number 7 (within-gene range 6–7): SLC30A8.
- chr8:117,055,818–122,781,071, 60 genes, copy number 7: AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1, MRPL13, MTBP, SNTB1, NCAPGP1, AC104958.1, AC104958.2, AC068413.1, AC011626.1, RPL35AP19, HAS2, HAS2-AS1, LINC02855, AC037486.1, MRPS36P3, SMILR, LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2.
- chr8:122,807,746–122,816,517, 1 gene, copy number 7: AC016405.1.

Autosomal genes at a single copy (total copy number 1): 1,515. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
